Somatic mutation profile of tumor specimen TCGA-A3-3308-01A (aliquot TCGA-A3-3308-01A-01W-0886-08) from TCGA case TCGA-A3-3308, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.4 years (28,287 days).
Specimen TCGA-A3-3308-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f9f5375-a9b7-4fd1-b258-b1a5aa520b0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3308-11A (Solid Tissue Normal), aliquot TCGA-A3-3308-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa2cd6cc-bc3b-4754-86e9-5f02acd6c034

The open-access MAF lists 88 somatic variants for this specimen: 64 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 45, Silent 24, Frame Shift Del 10, Nonsense Mutation 3, In Frame Del 2, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.437del p.L146* | Frame Shift Del (DEL) | VAF 47/236 reads (20%) | hotspot (GDC flag); catalogued as rs1114167627, COSV64292458; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 102/627 reads (16%) | hotspot (GDC flag); catalogued as CS110219, CS1314438, COSV64295775, COSV64297457, COSV64302278; called by muse, mutect2, varscan2
- ASB10 | c.1366C>T p.R456C (on ENST00000420175 / NM_001142459.2; = p.R441C on NM_080871.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs776358265, COSV99318067; called by muse, mutect2, varscan2
- BHLHE40 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56575573; called by mutect2, varscan2
- BRCA2 | c.8399C>G p.P2800R | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359087; ClinVar: uncertain significance; called by muse, mutect2
- CDCP2 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779292002; called by muse, mutect2, varscan2
- CSMD3 | c.10740T>G p.F3580L (on ENST00000297405 / NM_001363185.1; = p.F3411L on NM_052900.3) | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs1484852694; called by muse, varscan2
- FN1 | c.331A>C p.T111P | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100118561; called by muse, mutect2, varscan2
- GRIK1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); catalogued as rs963257580; called by muse, mutect2, varscan2
- HTR1A | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as rs201675006; called by muse, mutect2, varscan2
- MAP3K19 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs373802326; called by muse, mutect2, varscan2
- MFAP5 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 114/615 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865910671; called by muse, mutect2, varscan2
- MSR1 | c.1319C>A p.S440* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | catalogued as COSV50512301; called by muse, mutect2, varscan2
- MYOM1 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs570677625, COSV55288902; called by muse, mutect2, varscan2
- NYNRIN | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs748667976, COSV101230554; called by muse, mutect2, varscan2
- RAB11FIP1 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs1303714443; called by muse, mutect2, varscan2
- RSPH10B | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 95/174 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs374498782; called by muse, mutect2, varscan2
- SPRY4 | c.73C>T p.R25W (on ENST00000434127 / NM_001127496.3; = p.R48W on NM_030964.4) | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs753427357, COSV59986357; called by muse, mutect2, varscan2
- TDRD10 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 120/554 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs768196430, COSV100872929; called by muse, mutect2, varscan2
- TRAM1L1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60291867; called by muse, mutect2, varscan2
- TRIM67 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64158938; called by muse, mutect2, varscan2
- ASPM | c.3354T>A p.D1118E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ATP1A4 | c.1952C>G p.A651G | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ATP5MD | c.131del p.Y44Ffs*4 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- BAP1 | c.1975_1977del p.K659del | In Frame Del (DEL) | VAF 40/152 reads (26%) | called by pindel, varscan2
- CASP9 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC163 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CCDC57 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CDH6 | c.1021_1024del p.K341Cfs*36 | Frame Shift Del (DEL) | VAF 26/173 reads (15%) | called by mutect2, pindel, varscan2
- DCAF13 | c.61T>G p.L21V | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPS8 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EXOSC10 | c.285del p.S95Rfs*9 | Frame Shift Del (DEL) | VAF 93/494 reads (19%) | called by mutect2, pindel, varscan2
- HMCN1 | c.16672A>G p.T5558A | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL17RB | c.1004T>A p.L335H | Missense Mutation (SNP) | VAF 129/482 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INAVA | c.1282_1285del p.H428Tfs*3 | Frame Shift Del (DEL) | VAF 45/218 reads (21%) | called by pindel, varscan2
- KMT2D | c.3957T>A p.H1319Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- LGSN | c.744T>G p.Y248* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- LRRN3 | c.1750A>G p.N584D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by mutect2, varscan2
- MANEAL | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- OR2L2 | c.418T>C p.C140R | Missense Mutation (SNP) | VAF 158/722 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PATJ | c.1694T>C p.I565T | Missense Mutation (SNP) | VAF 131/533 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPIL4 | c.1059T>G p.D353E | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R7 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2B | c.2188C>T p.L730F | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RCC1 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RIF1 | c.6628A>C p.I2210L | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- RPE65 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETD2 | c.5465del p.P1822Qfs*16 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- SHMT2 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- SULT2A1 | c.398dup p.W134Lfs*8 | Frame Shift Ins (INS) | VAF 30/166 reads (18%) | called by mutect2, pindel, varscan2
- SWT1 | c.1585_1587del p.E529del | In Frame Del (DEL) | VAF 9/66 reads (14%) | called by pindel, varscan2
- SYCP2L | c.2055del p.E686Kfs*8 | Frame Shift Del (DEL) | VAF 48/241 reads (20%) | called by mutect2, pindel, varscan2
- TAF1 | c.4438G>T p.D1480Y (on ENST00000373790 / NM_138923.4; = p.D1501Y on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFB1M | c.48del p.T17Rfs*9 | Frame Shift Del (DEL) | VAF 26/164 reads (16%) | called by mutect2, pindel, varscan2
- TMPRSS3 | c.573-8_573-1del p.X191_splice | Splice Site (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- TTN | c.29632G>C p.A9878P (on ENST00000591111; = p.A8951P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/209 reads (16%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.22852C>T p.H7618Y (on ENST00000591111; = p.H6691Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | PolyPhen benign (0.003); called by muse, mutect2
- TXNDC11 | c.2729C>A p.A910D (on ENST00000356957 / NM_001303447.2; = p.A883D on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- USH2A | c.10720G>C p.G3574R | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- VHL | c.515_518del p.P172Rfs*29 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- WASL | c.1076C>A p.P359Q | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- WDHD1 | c.1947G>C p.M649I | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF347 | c.410del p.N137Ifs*21 | Frame Shift Del (DEL) | VAF 102/1032 reads (10%) | called by mutect2, pindel
- ZSCAN2 | c.1095dup p.E366Rfs*7 | Frame Shift Ins (INS) | VAF 45/393 reads (11%) | called by mutect2, pindel, varscan2
- AKAP13 | c.3384C>T p.A1128= | Silent (SNP) | VAF 29/233 reads (12%) | catalogued as rs200852061, COSV63461181; called by muse, mutect2, varscan2
- ANKRD55 | c.1158T>C p.D386= | Silent (SNP) | VAF 168/1028 reads (16%) | called by muse, varscan2
- CHD6 | c.7923G>A p.Q2641= | Silent (SNP) | VAF 46/141 reads (33%) | called by muse, mutect2, varscan2
- EFCC1 | c.1633C>T p.L545= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV101459994; called by muse, mutect2, varscan2
- FAM47B | c.1140C>T p.Y380= | Silent (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- IMPG2 | c.3276T>C p.C1092= | Silent (SNP) | VAF 49/271 reads (18%) | called by muse, mutect2, varscan2
- INPP5F | c.3207T>A p.S1069= | Silent (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- IQGAP1 | c.3486C>T p.F1162= | Silent (SNP) | VAF 64/280 reads (23%) | catalogued as COSV99185475; called by muse, mutect2, varscan2
- KIF25 | c.609G>A p.T203= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs147571413; called by muse, mutect2
- LMO7 | c.453G>A p.V151= (on ENST00000357063; = p.V166= on NM_005358.5) | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV58531561; called by muse, mutect2, varscan2
- MACF1 | c.18714T>C p.H6238= (on ENST00000372915; = p.H4283= on NM_012090.5) | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- MED6 | c.18C>T p.I6= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- MYO1D | c.2334G>A p.T778= | Silent (SNP) | VAF 50/298 reads (17%) | catalogued as rs969564116; called by muse, mutect2, varscan2
- NCAPG2 | c.2712A>G p.Q904= | Silent (SNP) | VAF 94/430 reads (22%) | catalogued as rs752571821; called by muse, mutect2, varscan2
- NLRP7 | c.444C>T p.D148= | Silent (SNP) | VAF 429/1175 reads (37%) | catalogued as rs781097722, COSV60171380; called by muse, mutect2, varscan2
- NOS1 | c.3231T>A p.A1077= | Silent (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- OR5H2 | c.6G>A p.S2= | Silent (SNP) | VAF 53/300 reads (18%) | catalogued as rs756216447, COSV62351076; called by muse, mutect2, varscan2
- PHF2 | c.780C>T p.H260= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs539206245, COSV100823244; called by muse, mutect2, varscan2
- PRG3 | c.282G>A p.R94= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- RIMBP3 | c.2895G>A p.T965= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs535277568; called by muse, mutect2, varscan2
- RNF17 | c.493T>C p.L165= | Silent (SNP) | VAF 64/215 reads (30%) | catalogued as rs1397730095; called by muse, mutect2, varscan2
- TGIF1 | c.456G>T p.V152= (on ENST00000330513 / NM_001374396.1; = p.V172= on NM_003244.4) | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- TPT1 | c.153T>C p.N51= | Silent (SNP) | VAF 23/137 reads (17%) | called by muse, mutect2, varscan2
- ZBTB10 | c.939T>C p.S313= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
